Somatic mutation profile of tumor specimen C3L-00583-03 (aliquot CPT0019150009) from CPTAC case C3L-00583, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 55.4 years (20,237 days).
Specimen C3L-00583-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7e86764d-bc20-48a0-84a0-f99c37ca926a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00583-31 (Blood Derived Normal), aliquot CPT0019900002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1890666c-6d75-44eb-ad8f-4befed50f91e

The open-access MAF lists 65 somatic variants for this specimen: 46 protein-altering or splice-affecting, 12 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 38, Silent 12, Intron 4, Frame Shift Del 3, Splice Site 2, Frame Shift Ins 2, 5'UTR 1, 5'Flank 1, RNA 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- VHL | c.343C>T p.H115Y | Missense Mutation (SNP) | VAF 132/224 reads (59%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs5030811, CD141839, CM961423, CM982005, COSV56545369, COSV56546151, COSV56556158, COSV56571206; called by muse, mutect2, varscan2
- ADAMTS12 | c.3860A>C p.E1287A | Missense Mutation (SNP) | VAF 119/397 reads (30%) | SIFT tolerated (0.35); PolyPhen benign (0.211); catalogued as rs1404984152, COSV100710369; called by muse, mutect2, varscan2
- CHRNA2 | c.503C>T p.T168M | Missense Mutation (SNP) | VAF 20/296 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as rs766076722, COSV99531962; ClinVar: uncertain significance; called by muse, mutect2
- CSMD2 | c.5636C>A p.S1879Y | Missense Mutation (SNP) | VAF 49/191 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV53962655; called by muse, mutect2, varscan2
- FUT6 | c.58C>G p.L20V | Missense Mutation (SNP) | VAF 56/204 reads (27%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.582); catalogued as COSV54606589; called by muse, mutect2, varscan2
- GCNT2 | c.263T>C p.L88P | Missense Mutation (SNP) | VAF 25/422 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); catalogued as rs143453847; called by muse, mutect2
- GNRHR | c.869A>T p.Y290F | Missense Mutation (SNP) | VAF 60/195 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM1111643; called by muse, mutect2, varscan2
- GPR148 | c.679G>A p.V227I | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs202053340; called by mutect2, varscan2
- KDM5C | c.826G>T p.E276* | Nonsense Mutation (SNP) | VAF 99/181 reads (55%) | catalogued as COSV64763119; called by muse, mutect2, varscan2
- MATR3 | c.953G>A p.R318Q | Missense Mutation (SNP) | VAF 82/552 reads (15%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.953); catalogued as rs1431850544; called by muse, mutect2, varscan2
- MEX3D | c.583G>A p.V195M | Missense Mutation (SNP) | VAF 34/351 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs773233571; called by muse, mutect2, varscan2
- MTOR | c.7292T>A p.L2431Q | Missense Mutation (SNP) | VAF 21/96 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63868562; called by muse, mutect2, varscan2
- NPSR1 | c.53C>T p.T18M | Missense Mutation (SNP) | VAF 72/389 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.006); catalogued as rs149663215; called by muse, mutect2, varscan2
- ZNF787 | c.1109G>A p.G370D | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0); catalogued as rs1174903192; called by muse, mutect2, varscan2
- ACACB | c.1630T>C p.F544L | Missense Mutation (SNP) | VAF 102/362 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- ATE1 | c.1461del p.K487Nfs*60 | Frame Shift Del (DEL) | VAF 65/274 reads (24%) | called by mutect2, pindel, varscan2
- BBOF1 | c.187del p.S63Vfs*5 | Frame Shift Del (DEL) | VAF 30/113 reads (27%) | called by mutect2, pindel, varscan2
- BLOC1S3 | c.409C>A p.R137S | Missense Mutation (SNP) | VAF 56/180 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.35); called by muse, mutect2, varscan2
- BRWD1 | c.56A>T p.Y19F | Missense Mutation (SNP) | VAF 125/303 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.405); called by muse, mutect2, varscan2
- BTG4 | c.202A>C p.K68Q | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT tolerated (0.51); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- COL8A2 | c.383C>T p.P128L | Missense Mutation (SNP) | VAF 61/207 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.478); called by muse, mutect2, varscan2
- CSE1L | c.80G>T p.R27L | Missense Mutation (SNP) | VAF 74/208 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- CTNNA2 | c.2602G>T p.A868S (on ENST00000402739 / NM_001282597.3; = p.A820S on NM_004389.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.588); called by mutect2, varscan2
- CYP51A1 | c.549dup p.E184Rfs*7 | Frame Shift Ins (INS) | VAF 44/293 reads (15%) | called by pindel, varscan2
- CYP51A1 | c.544G>A p.E182K | Missense Mutation (SNP) | VAF 51/282 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.599); called by muse, varscan2
- DNAJB13 | c.167G>C p.S56T | Missense Mutation (SNP) | VAF 52/158 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- DRICH1 | c.496G>T p.D166Y | Missense Mutation (SNP) | VAF 14/316 reads (4%) | SIFT tolerated, low confidence (0.15); PolyPhen probably damaging (0.979); called by muse, mutect2
- FANCA | c.614C>G p.A205G | Missense Mutation (SNP) | VAF 30/506 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.411); called by muse, mutect2
- FANCM | c.1432dup p.R478Pfs*11 | Frame Shift Ins (INS) | VAF 37/156 reads (24%) | called by mutect2, pindel, varscan2
- FBN3 | c.1399C>T p.P467S | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.902); called by muse, mutect2, varscan2
- GBP5 | c.1060C>G p.L354V | Missense Mutation (SNP) | VAF 99/344 reads (29%) | SIFT tolerated (0.41); PolyPhen benign (0.268); called by muse, mutect2, varscan2
- GCN1 | c.7563+1G>A p.X2521_splice | Splice Site (SNP) | VAF 50/114 reads (44%) | called by muse, mutect2, varscan2
- HMGCR | c.141T>G p.N47K | Missense Mutation (SNP) | VAF 78/221 reads (35%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.448); called by muse, mutect2, varscan2
- IMPG1 | c.1762A>C p.N588H | Missense Mutation (SNP) | VAF 55/106 reads (52%) | SIFT deleterious (0.03); PolyPhen benign (0.171); called by muse, mutect2, varscan2
- IPO9 | c.389A>G p.Y130C | Missense Mutation (SNP) | VAF 122/427 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- LINC02868 | n.87-1G>T | Splice Site (SNP) | VAF 46/139 reads (33%) | called by muse, mutect2, varscan2
- MTREX | c.559_562del p.F187Pfs*7 | Frame Shift Del (DEL) | VAF 33/102 reads (32%) | called by mutect2, pindel, varscan2
- NOTCH4 | c.1732C>T p.L578F | Missense Mutation (SNP) | VAF 9/174 reads (5%) | SIFT tolerated (0.14); PolyPhen benign (0.04); called by muse, mutect2
- PBRM1 | c.2264T>A p.V755D | Missense Mutation (SNP) | VAF 47/64 reads (73%) | SIFT deleterious (0); PolyPhen possibly damaging (0.667); called by muse, mutect2, varscan2
- PCDHB10 | c.1941T>A p.N647K | Missense Mutation (SNP) | VAF 352/1096 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.969); called by muse, varscan2
- SELP | c.244G>C p.V82L | Missense Mutation (SNP) | VAF 35/248 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- SPEG | c.7274G>C p.R2425P | Missense Mutation (SNP) | VAF 56/153 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TFAM | c.178T>A p.F60I | Missense Mutation (SNP) | VAF 158/452 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- TMEM131 | c.3836A>T p.K1279M | Missense Mutation (SNP) | VAF 71/223 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- VWA8 | c.5639C>G p.S1880C | Missense Mutation (SNP) | VAF 38/144 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- WDR86 | c.306G>T p.R102S | Missense Mutation (SNP) | VAF 47/314 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- CALML5 | c.159C>T p.I53= | Silent (SNP) | VAF 170/540 reads (31%) | catalogued as rs1323376519; called by muse, mutect2, varscan2
- DNAI3 | c.1428T>C p.N476= | Silent (SNP) | VAF 57/198 reads (29%) | catalogued as rs1225726526; called by muse, mutect2, varscan2
- EBAG9 | c.132T>C p.T44= | Silent (SNP) | VAF 27/104 reads (26%) | catalogued as rs1312285780; called by muse, mutect2, varscan2
- GPC4 | c.684G>A p.A228= | Silent (SNP) | VAF 20/32 reads (63%) | catalogued as rs757883865; called by muse, mutect2, varscan2
- KRT15 | c.288C>T p.G96= | Silent (SNP) | VAF 83/271 reads (31%) | catalogued as rs768785185; called by muse, mutect2, varscan2
- MUC5AC | c.14839C>T p.L4947= | Silent (SNP) | VAF 93/387 reads (24%) | called by muse, mutect2, varscan2
- MYCBP2 | c.5061T>C p.A1687= (on ENST00000357337; = p.A1725= on NM_015057.5) | Silent (SNP) | VAF 81/298 reads (27%) | called by muse, mutect2, varscan2
- PCF11 | c.4653A>G p.T1551= | Silent (SNP) | VAF 32/103 reads (31%) | called by muse, mutect2, varscan2
- TIMD4 | c.378C>T p.N126= | Silent (SNP) | VAF 54/138 reads (39%) | catalogued as rs761841993; called by muse, mutect2
- TNKS | c.870T>C p.A290= | Silent (SNP) | VAF 46/171 reads (27%) | called by muse, mutect2, varscan2
- TPTE | c.312G>C p.L104= (on ENST00000618007 / NM_199261.4; = p.L86= on NM_199259.4) | Silent (SNP) | VAF 82/314 reads (26%) | called by muse, mutect2, varscan2
- UNC13B | c.4206C>T p.I1402= | Silent (SNP) | VAF 59/105 reads (56%) | called by muse, mutect2, varscan2
- ATL2 | c.118+1025T>A | Intron (SNP) | VAF 7/19 reads (37%) | catalogued as rs143781075; called by muse, mutect2, varscan2
- DNAH14 | c.2938+1982A>G | Intron (SNP) | VAF 61/212 reads (29%) | called by muse, mutect2, varscan2
- ERLIN2 | chr8:37736077 A>T | 5'Flank (SNP) | VAF 6/25 reads (24%) | called by muse, mutect2, varscan2
- HSPB1 | c.-14C>T | 5'UTR (SNP) | VAF 205/585 reads (35%) | called by muse, mutect2, varscan2
- LYPLA2 | c.646-14_646-13del | Intron (DEL) | VAF 32/172 reads (19%) | catalogued as rs758462947; called by pindel, varscan2
- OPLAH | c.2512-33C>T | Intron (SNP) | VAF 121/400 reads (30%) | catalogued as rs1279438708; called by muse, mutect2, varscan2
- SPATA31C2 | n.1939del | RNA (DEL) | VAF 184/500 reads (37%) | called by mutect2, pindel, varscan2
